Somatic mutation profile of tumor specimen TCGA-HC-7740-01A (aliquot TCGA-HC-7740-01A-11D-2114-08) from TCGA case TCGA-HC-7740, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 59.9 years (21,883 days).
Specimen TCGA-HC-7740-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9f65c848-4a80-41f1-b4b1-b83038b5b9b9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HC-7740-10A (Blood Derived Normal), aliquot TCGA-HC-7740-10A-01D-2115-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5a88b2a4-64b8-4617-97fb-397b6423774e

The open-access MAF lists 20 somatic variants for this specimen: 15 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 13, Silent 5, Nonsense Mutation 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GRIN2A | c.325G>A p.V109I | Missense Mutation (SNP) | VAF 11/134 reads (8%) | SIFT tolerated (0.83); PolyPhen benign (0.001); catalogued as COSV100410155, COSV58027171; called by muse, mutect2
- HHAT | c.647A>C p.N216T | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.202); catalogued as COSV54810667, COSV54810902; called by muse, mutect2, varscan2
- IL1RAPL2 | c.762T>A p.D254E | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.08); catalogued as rs1198584195, COSV61185251; called by muse, mutect2, varscan2
- MRTFB | c.209G>A p.G70D | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57962205; called by muse, mutect2, varscan2
- NSD3 | c.2623C>T p.Q875* | Nonsense Mutation (SNP) | VAF 12/62 reads (19%) | catalogued as COSV57674555; called by muse, mutect2, varscan2
- PROS1 | c.221A>T p.N74I | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62399803; called by muse, mutect2, varscan2
- PTPN9 | c.610C>G p.L204V | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.221); catalogued as COSV60726213; called by muse, varscan2
- RYBP | c.125C>T p.T42I | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.264); catalogued as COSV72181165; called by muse, mutect2
- SEMA3D | c.2128C>T p.R710W | Missense Mutation (SNP) | VAF 7/115 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as rs1265790609, COSV52387550; called by muse, mutect2
- SHC1 | c.283G>A p.V95I | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0.011); catalogued as COSV58316920; called by muse, mutect2
- SMARCC2 | c.3529G>C p.V1177L | Missense Mutation (SNP) | VAF 11/138 reads (8%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); catalogued as COSV53240987; called by muse, mutect2
- SPAG9 | c.997G>T p.A333S (on ENST00000262013 / NM_001130528.3; = p.A319S on NM_003971.6) | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV56244558; called by muse, mutect2
- SPEN | c.9566A>G p.Y3189C | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV65367875; called by muse, mutect2, varscan2
- TIGD5 | c.1361T>C p.L454P | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55309419; called by muse, mutect2, varscan2
- NAA25 | c.1863_1865del p.L623del | In Frame Del (DEL) | VAF 7/69 reads (10%) | called by mutect2, pindel, varscan2
- HPS5 | c.2277A>G p.G759= (on ENST00000349215 / NM_181507.2; = p.G645= on NM_007216.4) | Silent (SNP) | VAF 12/154 reads (8%) | catalogued as rs752195294, COSV61688098; called by muse, mutect2
- MYOM3 | c.960G>A p.K320= | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as COSV58401680; called by muse, mutect2, varscan2
- PDE1C | c.1425G>A p.S475= | Silent (SNP) | VAF 7/75 reads (9%) | catalogued as rs763131623, COSV58515001; called by muse, mutect2
- RYR1 | c.369C>T p.S123= | Silent (SNP) | VAF 9/119 reads (8%) | catalogued as COSV62112163; called by muse, mutect2
- ZHX3 | c.1374C>T p.P458= | Silent (SNP) | VAF 11/68 reads (16%) | catalogued as COSV58389004; called by muse, mutect2, varscan2
